Gene-level copy-number profile of tumor specimen TCGA-BF-A5EQ-01A from TCGA case TCGA-BF-A5EQ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 63.9 years (23,353 days).
Specimen TCGA-BF-A5EQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.75f6b860-4965-4ea6-a697-9cc6aebe56ff.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BF-A5EQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f46b47c6-a3ac-4333-b03a-67f2ae66a2aa

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 5,796; copy number 3: 17,815; copy number 4: 26,970; copy number 5: 5,874; copy number 6: 2,522; copy number 7: 161; copy number 8: 179; copy number 9: 82; copy number 10: 18; copy number 11: 167; copy number 12: 39; copy number 13: 11; copy number 16: 109; copy number 19: 66.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BF-A5EQ-01A-21D-A27J-01): tumor purity 0.58, ploidy 3.74, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 492 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:68,430,427–69,131,069, 12 genes, copy number 9 (within-gene range 5–9): AC010280.2, AC010280.1, AC010280.3, AC093523.1, VWA8P1, U8, AC093248.1, RN7SKP251, LINC02198, AC010273.3, SUMO2P4, SLC30A5.
- chr5:72,087,782–72,209,565, 3 genes, copy number 12: AC025774.1, MAP1B, MIR4803.
- chr5:72,574,120–72,660,669, 1 gene, copy number 13 (within-gene range 11–13): LINC02056.
- chr5:77,210,449–77,638,713, 6 genes, copy number 9 (within-gene range 8–9): PDE8B, ALDH7A1P1, WDR41, RPS2P24, RPL7P23, OTP.
- chr5:78,708,734–82,386,977, 76 genes, copy number 9–16 (within-gene range 7–16) (broad region; genes not listed).
- chr5:126,600,925–127,664,029, 25 genes, copy number 10–12: PHAX, AC099513.1, TEX43, BOLA3P3, HSPE1P10, LMNB1-DT, RNU6-752P, LMNB1, MARCHF3, C5orf63, AC005915.1, MRPS5P3, AC011416.1, SELENOTP2, AC011416.2, AC011416.3, AC011416.4, MEGF10, AC010424.1, AC010424.2, HNRNPKP1, PRRC1, AC010424.3, CTXN3, AC022118.1.
- chr5:137,617,500–138,575,675, 34 genes, copy number 11: KLHL3, MIR874, HNRNPA0, AC106791.3, AC106791.2, NPY6R, AC106791.1, MYOT, PKD2L2, FAM13B, AC113382.1, AC113382.2, RNU6-1148P, WNT8A, NME5, RNU6-460P, RNU6-888P, BRD8, KIF20A, CDC23, GFRA3, RPS27AP18, CDC25C, FAM53C, AC104116.1, KDM3B, REEP2, AC113403.1, EGR1, RPL7P19, ETF1, HSPA9, SNORD63B, SNORD63.
- chr5:176,346,062–176,659,054, 19 genes, copy number 12: KIAA1191, AC138956.1, AC138956.2, ARL10, MIR1271, NOP16, HIGD2A, CLTB, AC010297.1, FAF2, RNF44, CDHR2, RN7SL684P, Y_RNA, GPRIN1, SNCB, MIR4281, EIF4E1B, TSPAN17.
- chr15:64,963,022–65,076,690, 6 genes, copy number 9: SPG21, MTFMT, AC013553.2, SLC51B, AC013553.3, RASL12.
- chr22:20,314,238–22,465,986, 169 genes, copy number 11–16 (broad region; genes not listed).
- chr22:40,410,281–40,636,719, 1 gene, copy number 11 (within-gene range 4–11): MRTFA.
- chr22:40,521,800–43,964,488, 126 genes, copy number 11–19 (broad region; genes not listed).
- chr22:43,957,027–43,957,348, 1 gene, copy number 19: RPL35AP36.
- chr22:44,413,485–44,737,681, 10 genes, copy number 13: Z85994.2, LINC01656, MRPS18CP6, AL023973.1, RTL6, KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5.
- chr22:45,875,932–45,977,162, 3 genes, copy number 11: BX324167.2, BX324167.1, WNT7B.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
